Gene-level copy-number profile of tumor specimen TCGA-EY-A1GV-01A from TCGA case TCGA-EY-A1GV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 75.5 years (27,581 days).
Specimen TCGA-EY-A1GV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.56b14a4b-e32b-4aae-b4fa-6c4b89e59d50.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A1GV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1fed628a-bcf7-4444-982d-7c6deaf5bfb9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,063; copy number 4: 43,386; copy number 5: 937; copy number 6: 5,604; copy number 7: 326; copy number 8: 308; copy number 9: 6; copy number 11: 91; copy number 13: 88.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A1GV-01A-11D-A13J-01): tumor purity 0.32, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 185 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:188,153,284–188,890,671, 1 gene, copy number 11 (within-gene range 6–11): LPP.
- chr3:188,562,238–189,325,304, 5 genes, copy number 11 (within-gene range 6–11): LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1.
- chr5:78,222,184–78,480,739, 6 genes, copy number 9: ATP6V1G1P6, AC104108.1, RNU6-183P, Y_RNA, SCAMP1-AS1, SCAMP1.
- chr14:21,962,819–22,518,871, 85 genes, copy number 11 (broad region; genes not listed).
- chr19:39,236,433–40,765,389, 88 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
